TCGA case TCGA-CZ-4854 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2efcefca-5e52-4b3d-a48a-9e9c73cc0141

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 1,404 days (3.8 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,876 days); Year of diagnosis: 2005; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,404 days (3.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Molecular and laboratory tests
- Leukocytes: Normal.
- Calcium: Low.
- Hemoglobin: Low.
- Platelets: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-4854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1.7; Shortest dimension: 0.4.
  Slide TCGA-CZ-4854-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CZ-4854-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CZ-4854-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-4854-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 0.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -4809.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy bladder cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,404 days; disease-specific survival: no event (censored), 1,404 days; progression-free interval: no event (censored), 1,404 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CZ-4854-01): tumor purity 0.61, ploidy 2.54, whole-genome doublings 1 (call status: legacy_call).
